Somatic mutation profile of tumor specimen TCGA-AA-3681-01A (aliquot TCGA-AA-3681-01A-01W-0900-09) from TCGA case TCGA-AA-3681, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage III; Age at diagnosis: 77.8 years (28,399 days).
Specimen TCGA-AA-3681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52b2facc-95c8-40e1-9631-14d8874a89a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3681-10A (Blood Derived Normal), aliquot TCGA-AA-3681-10A-01W-0900-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/136dba0f-a6c1-4344-9614-6420a49f51fb

The open-access MAF lists 129 somatic variants for this specimen: 97 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 88, Silent 29, Nonsense Mutation 4, Intron 2, Frame Shift Del 1, Splice Region 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 91/204 reads (45%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1394G>A p.R465H (on ENST00000281708 / NM_001349798.2; = p.R385H on NM_018315.5) | Missense Mutation (SNP) | VAF 91/325 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519895, COSV55891746, COSV55897262, COSV55941157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 121/194 reads (62%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs985033810, CM056069, CM070298, COSV52661058, COSV52724858, COSV52839584; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TRAF7 | c.1558A>T p.N520Y | Missense Mutation (SNP) | VAF 5/9 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58213720, COSV58214891, COSV58219060; called by muse, mutect2, varscan2
- ABCG1 | c.1987C>T p.R663C | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1302262582, COSV59200688, COSV59207718; called by muse, mutect2
- AC013489.1 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 43/79 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs912398551, COSV51551210, COSV51554431; called by muse, mutect2, varscan2
- ADAM33 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769362525, COSV62937325; called by muse, mutect2, varscan2
- ANK2 | c.3556G>C p.G1186R | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52194319; called by muse, mutect2, varscan2
- APC | c.2770A>T p.R924* | Nonsense Mutation (SNP) | VAF 29/136 reads (21%) | catalogued as COSV57390321; called by muse, mutect2, varscan2
- ASIC5 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as rs752632438, COSV73332561, COSV73332754; called by muse, mutect2, varscan2
- ATG2B | c.3562G>T p.E1188* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV55892481; called by muse, mutect2, varscan2
- BBS10 | c.2079G>T p.Q693H | Missense Mutation (SNP) | VAF 116/251 reads (46%) | SIFT tolerated (0.84); PolyPhen benign (0.023); catalogued as COSV67913480; called by muse, mutect2, varscan2
- CCR7 | c.536G>T p.C179F | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55851087; called by muse, mutect2, varscan2
- CDC73 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV66466598, COSV66468203; called by muse, mutect2, varscan2
- CEACAM20 | c.481G>T p.D161Y | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57603678; called by muse, mutect2, varscan2
- CEP104 | c.2422G>A p.G808R | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs151278058; called by muse, mutect2, varscan2
- CFAP47 | c.1514C>T p.S505L | Missense Mutation (SNP) | VAF 105/182 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0.077); catalogued as rs762876322, COSV52881324, COSV52884138; called by muse, mutect2, varscan2
- CFH | c.3554C>A p.A1185D | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV66414904; called by muse, mutect2, varscan2
- CHD7 | c.6122C>T p.S2041F | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV101418409, COSV71115607; called by muse, mutect2, varscan2
- CHRNG | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV67315175, COSV67316165; called by muse, mutect2, varscan2
- COL6A3 | c.9130G>A p.V3044I | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs374628435; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPSF6 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV57013845, COSV57019048; called by muse, mutect2, varscan2
- CSDE1 | c.1402C>G p.L468V (on ENST00000358528 / NM_001007553.3; = p.L437V on NM_007158.6) | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV54763502; called by muse, mutect2, varscan2
- CYP4F8 | c.445C>T p.R149C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs558107890, COSV57853829; called by muse, mutect2, varscan2
- DIP2A | c.2968G>A p.V990M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as rs375730938; called by muse, varscan2
- DNAJC13 | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.23); catalogued as rs771705485, COSV53460117; called by muse, mutect2, varscan2
- DOCK9 | c.4002dup p.T1335Yfs*4 (on ENST00000376460 / NM_001366676.2; = p.T1336Yfs*4 on NM_015296.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 24/46 reads (52%) | catalogued as rs1344550381; called by mutect2, varscan2
- EDNRB | c.460C>T p.R154W (on ENST00000377211 / NM_001201397.1; = p.R64W on NM_000115.5) | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs139147111; called by muse, mutect2, varscan2
- EIF2AK4 | c.4691A>G p.N1564S | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs1193129637, COSV51116150; called by muse, varscan2
- EMID1 | c.706C>T p.R236W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.257); catalogued as rs555505087, COSV61830096; called by muse, mutect2
- EPHB2 | c.1819G>A p.E607K (on ENST00000400191 / NM_001309193.2; = p.E608K on NM_004442.7) | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); catalogued as COSV65863740; called by muse, mutect2, varscan2
- FAM186B | c.2383G>A p.V795I | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775908209, COSV57724587; called by muse, mutect2, varscan2
- FBLN2 | c.3325G>A p.A1109T | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs1272556761, COSV55480844; called by muse, mutect2, varscan2
- FBXO4 | c.898+4A>G | Splice Region (SNP) | VAF 43/127 reads (34%) | catalogued as COSV55854613; called by muse, mutect2, varscan2
- FLG | c.296A>G p.H99R | Missense Mutation (SNP) | VAF 42/153 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV64251949; called by muse, mutect2, varscan2
- FRYL | c.2863T>A p.L955I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV51965216; called by muse, mutect2, varscan2
- GABRA6 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 132/290 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1171764369, COSV50899755; called by muse, mutect2
- GABRQ | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 97/159 reads (61%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1412971894, COSV64781395; called by muse, mutect2, varscan2
- GALNT17 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.992); catalogued as rs1400903913, COSV61147106, COSV61164664; called by muse, mutect2, varscan2
- GNAS | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs766422930, COSV58332649; called by muse, varscan2
- GRK4 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs146194528; called by muse, mutect2, varscan2
- GUCY2C | c.221T>C p.L74P | Missense Mutation (SNP) | VAF 83/117 reads (71%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.682); catalogued as COSV53796913; called by muse, mutect2, varscan2
- HECTD4 | c.5612G>T p.W1871L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV66401621; called by muse, mutect2, varscan2
- INTS3 | c.3118G>T p.D1040Y | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55166241; called by muse, mutect2, varscan2
- ITIH2 | c.1637C>T p.T546M | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.488); catalogued as rs779849424, COSV64435636; called by muse, mutect2, varscan2
- KCNK9 | c.908G>A p.R303H | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57279943; called by muse, mutect2, varscan2
- KLHL38 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs375513752, COSV58087063; called by muse, mutect2, varscan2
- KLHL4 | c.1473T>A p.N491K | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV64149233; called by muse, mutect2, varscan2
- KRTAP4-3 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.615); catalogued as rs369554170; called by muse, varscan2
- LAMB4 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs751482652, COSV104391500, COSV52715777; called by muse, mutect2, varscan2
- LATS1 | c.2369T>C p.M790T | Missense Mutation (SNP) | VAF 140/493 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53602064; called by muse, mutect2, varscan2
- LRRK1 | c.1118-1G>A p.X373_splice | Splice Site (SNP) | VAF 138/204 reads (68%) | catalogued as COSV99437267; called by mutect2, varscan2
- LSM1 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1209698358, COSV60950137; called by muse, mutect2, varscan2
- MTUS2 | c.1960G>A p.A654T | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.168); catalogued as COSV70924672; called by muse, mutect2, varscan2
- NCAM2 | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 5/149 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV99520767; called by muse, mutect2
- NCKAP5 | c.3863C>T p.T1288M | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as rs765048071, COSV58445155; called by muse, mutect2, varscan2
- NEXMIF | c.3225C>A p.D1075E | Missense Mutation (SNP) | VAF 246/444 reads (55%) | SIFT tolerated (0.33); PolyPhen benign (0.361); catalogued as COSV50181176; called by muse, mutect2, varscan2
- NUP42 | c.629G>C p.G210A | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99330842; called by muse, mutect2, varscan2
- OR2B11 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 91/383 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.026); catalogued as COSV59511913; called by muse, mutect2, varscan2
- OTULIN | c.962C>G p.T321S | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV52507576; called by muse, mutect2, varscan2
- PAK3 | c.1157G>T p.C386F (on ENST00000262836 / NM_001324328.2; = p.C371F on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 129/272 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53281838; called by muse, mutect2, varscan2
- PCDH10 | c.1382C>T p.P461L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); catalogued as COSV52106296; called by muse, mutect2, varscan2
- PCDHB12 | c.1879G>A p.A627T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.079); catalogued as rs782361618, COSV53398854, COSV53402211; called by muse, mutect2, varscan2
- PDCL | c.506G>T p.G169V | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.158); catalogued as COSV52343790; called by muse, mutect2, varscan2
- PHF20L1 | c.2301G>C p.K767N | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774205944, COSV55199666, COSV99621009; called by muse, mutect2, varscan2
- PKHD1L1 | c.9580G>A p.G3194R | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65755912; called by muse, mutect2, varscan2
- POLR1E | c.1306G>C p.A436P (on ENST00000377792 / NM_001282766.1; = p.A374P on NM_022490.4) | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66773287; called by muse, mutect2
- PRSS12 | c.2365C>G p.L789V | Missense Mutation (SNP) | VAF 72/286 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56611413; called by muse, mutect2, varscan2
- RTL5 | c.1597C>T p.R533C | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.551); catalogued as rs752851219, COSV65452311; called by muse, mutect2, varscan2
- SEMA3D | c.1999G>A p.A667T | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.778); catalogued as COSV52407355; called by muse, mutect2, varscan2
- SFTPB | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs370715446; called by muse, mutect2, varscan2
- SORCS3 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.658); catalogued as rs367942325, COSV100863627; called by muse, mutect2, varscan2
- SPATA13 | c.730G>A p.V244I | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.701); catalogued as rs1042925088, COSV57982305; called by muse, mutect2, varscan2
- STIM1 | c.1844G>A p.R615H | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs145197758; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYVN1 | c.566T>G p.F189C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.829); catalogued as COSV53697783; called by muse, mutect2, varscan2
- TBC1D19 | c.1300C>T p.R434* | Nonsense Mutation (SNP) | VAF 61/223 reads (27%) | catalogued as rs141345574; called by muse, mutect2, varscan2
- TDRD7 | c.2132T>C p.L711P | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62431326; called by muse, mutect2, varscan2
- TENM3 | c.6683G>A p.R2228H | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.98); catalogued as rs201200379, COSV69300412; called by muse, mutect2, varscan2
- TMCC1 | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 58/210 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61443265; called by muse, mutect2, varscan2
- TRERF1 | c.1327C>T p.R443W | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.638); catalogued as rs371552696, COSV61679317; called by muse, mutect2, varscan2
- TRIM50 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs781863428, COSV60796294; called by muse, mutect2, varscan2
- TRIO | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as rs1476490075, COSV60099673; called by muse, mutect2, varscan2
- TSSK1B | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs373083902; called by muse, mutect2, varscan2
- TUT7 | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 60/214 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV52899725; called by muse, mutect2, varscan2
- UBXN4 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV55638770; called by muse, mutect2, varscan2
- USF3 | c.4600T>G p.S1534A | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as COSV57078334; called by muse, mutect2, varscan2
- USP3 | c.1146A>C p.L382F | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV99165622; called by muse, mutect2
- USP3 | c.1148A>T p.Y383F | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99165623; called by muse, mutect2
- UTP6 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV55576339; called by muse, mutect2, varscan2
- WHRN | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.493); catalogued as rs1301232723, COSV54335582; called by muse, mutect2
- XIRP2 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as rs780403837, COSV54695932, COSV99746418; called by muse, mutect2, varscan2
- ZMYM5 | c.1273A>G p.K425E | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT tolerated (0.16); PolyPhen benign (0.142); catalogued as COSV61990584; called by mutect2, varscan2
- ZSCAN4 | c.445C>T p.P149S | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV99989692; called by muse, mutect2, varscan2
- CUX2 | c.3538_3540del p.K1180del | In Frame Del (DEL) | VAF 11/50 reads (22%) | called by mutect2, pindel, varscan2
- LILRB3 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 24/150 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.283); called by muse, varscan2
- ZFR | c.3056_3057del p.R1019Tfs*24 | Frame Shift Del (DEL) | VAF 36/216 reads (17%) | called by pindel, varscan2
- BRSK1 | c.591G>A p.A197= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs374051558, COSV58666561; called by muse, mutect2, varscan2
- CASP8AP2 | c.4899T>G p.A1633= | Silent (SNP) | VAF 26/84 reads (31%) | catalogued as COSV52750608; called by muse, mutect2, varscan2
- CLSTN1 | c.942C>T p.C314= (on ENST00000377298 / NM_001009566.3; = p.C304= on NM_014944.4) | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as rs183348898, COSV63651890; called by muse, mutect2, varscan2
- DEUP1 | c.1482T>C p.Y494= | Silent (SNP) | VAF 3/20 reads (15%) | catalogued as COSV99976615; called by muse, mutect2
- DLL1 | c.2124C>T p.Y708= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs150208957; ClinVar: likely benign; called by muse, mutect2, varscan2
- DRAM2 | c.264C>A p.I88= | Silent (SNP) | VAF 44/178 reads (25%) | catalogued as COSV54416691; called by muse, mutect2, varscan2
- HS3ST1 | c.144C>T p.N48= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs780657270; called by muse, mutect2
- KCND2 | c.327C>T p.H109= | Silent (SNP) | VAF 57/138 reads (41%) | catalogued as rs764237787, COSV100478320, COSV58567402; called by muse, mutect2, varscan2
- KMT2C | c.4770A>G p.A1590= | Silent (SNP) | VAF 82/413 reads (20%) | catalogued as COSV51516426; called by muse, mutect2, varscan2
- LRRC3B | c.522G>A p.T174= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs181467821, COSV67523019; called by muse, mutect2, varscan2
- MAGI1 | c.3942C>T p.A1314= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs141542625; called by muse, mutect2, varscan2
- NBAS | c.2514G>A p.T838= | Silent (SNP) | VAF 82/289 reads (28%) | catalogued as rs777864312, COSV55737106, COSV55741449; called by muse, mutect2, varscan2
- NGRN | c.303C>G p.S101= | Silent (SNP) | VAF 17/139 reads (12%) | catalogued as COSV58961992; called by muse, mutect2, varscan2
- NUP210L | c.4248C>T p.I1416= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs765180961, COSV55159955; called by muse, mutect2, varscan2
- OOEP | c.291C>T p.F97= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as rs1370736514, COSV64859312; called by muse, mutect2, varscan2
- PCDH17 | c.333C>T p.N111= | Silent (SNP) | VAF 15/27 reads (56%) | catalogued as rs1363153167, COSV64972520; called by muse, mutect2, varscan2
- PCDHA11 | c.1749G>A p.S583= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs782301779, COSV56488926; called by muse, mutect2, varscan2
- PIEZO2 | c.7515T>G p.S2505= | Silent (SNP) | VAF 34/205 reads (17%) | catalogued as rs945349952, COSV53295579; called by muse, mutect2, varscan2
- PROX1 | c.1638C>T p.T546= | Silent (SNP) | VAF 74/273 reads (27%) | catalogued as rs1281642490, COSV54784569, COSV54784915; called by muse, mutect2, varscan2
- PUS10 | c.1320C>T p.I440= | Silent (SNP) | VAF 36/172 reads (21%) | catalogued as COSV57455408; called by muse, mutect2
- RRAGD | c.711G>T p.L237= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as COSV63270481; called by muse, mutect2, varscan2
- RSPH9 | c.471C>T p.G157= | Silent (SNP) | VAF 156/309 reads (50%) | catalogued as rs772977982, COSV64664250; called by muse, mutect2, varscan2
- SIX4 | c.2176T>C p.L726= | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs1279448000, COSV53671936; called by muse, mutect2, varscan2
- SLC24A2 | c.690C>A p.I230= | Silent (SNP) | VAF 17/159 reads (11%) | catalogued as COSV53878633; called by muse, mutect2, varscan2
- SLITRK4 | c.1650C>T p.S550= | Silent (SNP) | VAF 12/224 reads (5%) | catalogued as rs1163109428, COSV62024193, COSV62024335; called by muse, mutect2
- TEX15 | c.7863T>C p.N2621= (on ENST00000256246; = p.N3004= on NM_001350162.2) | Silent (SNP) | VAF 54/140 reads (39%) | catalogued as COSV56355716; called by muse, mutect2, varscan2
- TYR | c.237G>A p.S79= | Silent (SNP) | VAF 30/94 reads (32%) | catalogued as rs376813190; called by muse, mutect2, varscan2
- USH2A | c.12021C>T p.D4007= | Silent (SNP) | VAF 80/297 reads (27%) | catalogued as rs1387370996, COSV100236002, COSV56390348; called by muse, mutect2, varscan2
- USP16 | c.1248G>A p.E416= | Silent (SNP) | VAF 43/192 reads (22%) | catalogued as COSV57628476; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852039 G>A | 3'Flank (SNP) | VAF 27/44 reads (61%) | called by muse, mutect2, varscan2
- GH2 | c.456+12A>G | Intron (SNP) | VAF 29/96 reads (30%) | catalogued as rs1219170878, COSV60428174; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85669C>T | Intron (SNP) | VAF 49/183 reads (27%) | catalogued as rs538461825, COSV72276023; called by muse, mutect2, varscan2
